CCDI case PBBXRP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b7399e79-6d9f-40dd-ba23-200d29a50990

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 17.5 years (6,392 days).

Biospecimens (4 samples)
- Samples 0DK0AC, 0DK0AJ (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK0AQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKDDA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
